Gene-level copy-number profile of tumor specimen TCGA-18-3415-01A from TCGA case TCGA-18-3415, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.8 years (28,430 days).
Specimen TCGA-18-3415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.786d7879-e0a6-4102-ba3f-585322a5af85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3415-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9180bec4-02a5-4abc-8c00-beb4ce520288

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 1,611; copy number 2: 23,651; copy number 3: 23,023; copy number 4: 8,003; copy number 5: 1,711; copy number 6: 1,477; copy number 7: 256; copy number 8: 4; copy number 9: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3415-01A-01D-0978-01): tumor purity 0.48, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,716,105–23,438,700, 63 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 269 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,543,246–174,378,005, 214 genes, copy number 7 (broad region; genes not listed).
- chr3:188,153,284–188,890,671, 1 gene, copy number 7 (within-gene range 6–7): LPP.
- chr3:188,562,238–190,892,429, 25 genes, copy number 7: LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr10:5,498,697–5,554,329, 5 genes, copy number 9: CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3.
- chr11:13,610,363–14,364,506, 16 genes, copy number 7: HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2.
- chr12:75,649,195–75,698,816, 4 genes, copy number 8: AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:90,576,402–90,889,917, 1 gene, copy number 9 (within-gene range 2–9): LINC02822.
- chr12:90,809,207–90,955,176, 3 genes, copy number 9: AC112481.1, CCER1, LINC00615.

Autosomal genes at a single copy (total copy number 1): 877. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
